Somatic mutation profile of tumor specimen MMRF_2018_1_BM_CD138pos (aliquot MMRF_2018_1_BM_CD138pos_T1_KBS5U_L07215) from MMRF case MMRF_2018, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.1 years (25,962 days).
Specimen MMRF_2018_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72d53da9-84f2-43af-9f40-495365d374b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2018_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2018_1_PB_Whole_C2_KBS5U_L07216; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2ed84ae-a7b4-4d15-89f2-1bdad634d95d

The open-access MAF lists 100 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 24, Intron 11, Silent 10, 5'UTR 6, 3'Flank 3, 5'Flank 3, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLH1 | c.117-1G>A p.X39_splice | Splice Site (SNP) | VAF 65/212 reads (31%) | catalogued as rs587779950, CS093757, CS1314320; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.962A>G p.N321S (on ENST00000326195 / NM_001025091.2; = p.N283S on NM_001090.3) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs200316293; called by muse, mutect2, varscan2
- CAPN8 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1389121191, COSV64815493; called by muse, mutect2, varscan2
- CSPG4 | c.4363C>T p.R1455C | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs376454040; called by muse, mutect2, varscan2
- EFCAB12 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs574254518; called by muse, mutect2, varscan2
- GLRB | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100029815; called by muse, mutect2, varscan2
- GRID2IP | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs761869402; called by muse, mutect2, varscan2
- IGHV2-70 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as rs369407281; called by muse, varscan2
- IGLC2 | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs528109051; called by muse, mutect2, varscan2
- IGLL5 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs545109780, COSV101597155; called by muse, varscan2
- NEGR1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs373419972; called by muse, mutect2, varscan2
- NHS | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66271555; called by muse, mutect2, varscan2
- NKD1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs933448498; called by muse, mutect2, varscan2
- NLRP8 | c.1869C>A p.S623R | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99079395; called by muse, mutect2, varscan2
- PCNX3 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769509369, COSV63136791; called by muse, mutect2, varscan2
- PENK | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV59240781; called by muse, mutect2
- SLITRK3 | c.1817A>T p.E606V | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs753049790, COSV99579988; called by muse, mutect2, varscan2
- SPATA31E1 | c.2450A>G p.H817R | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as rs765621155; called by muse, mutect2
- ZNF765 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 96/354 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1166220082; called by muse, mutect2, varscan2
- A2ML1 | c.713T>G p.V238G | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ABCA1 | c.6140G>A p.G2047E | Missense Mutation (SNP) | VAF 144/256 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADH6 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALG6 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP250 | c.4336G>A p.E1446K | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CNP | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A1 | c.1855G>T p.G619C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREBBP | c.4117C>G p.P1373A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DACH1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- FAAP100 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- HECTD4 | c.6104A>G p.N2035S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOGA1 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HYAL1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- IGLV3-21 | c.334A>C p.S112R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, varscan2
- METTL3 | c.1193G>A p.W398* | Nonsense Mutation (SNP) | VAF 68/148 reads (46%) | called by muse, mutect2, varscan2
- PLCL2 | c.2479G>A p.V827M (on ENST00000615277 / NM_001144382.2; = p.V701M on NM_015184.5) | Missense Mutation (SNP) | VAF 192/273 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- RAD21 | c.1074_1093del p.K359Dfs*18 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- SCN5A | c.5671C>A p.P1891T (on ENST00000333535 / NM_198056.3; = p.P1890T on NM_000335.5) | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA3A | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 130/228 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SEMA5A | c.2489A>G p.Y830C | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SERPINI2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMPDL3A | c.116A>C p.Q39P | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- UCHL3 | c.433del p.R145Efs*18 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- ZNF93 | c.1358A>T p.Y453F | Missense Mutation (SNP) | VAF 149/246 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AASS | c.1692G>A p.K564= | Silent (SNP) | VAF 59/176 reads (34%) | called by muse, mutect2, varscan2
- ITPR1 | c.1983C>T p.N661= (on ENST00000354582; = p.N646= on NM_002222.7) | Silent (SNP) | VAF 56/174 reads (32%) | catalogued as rs369495242; called by muse, mutect2, varscan2
- LCP1 | c.972A>T p.G324= | Silent (SNP) | VAF 72/169 reads (43%) | called by muse, mutect2, varscan2
- LINGO1 | c.960C>T p.G320= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1157304705, COSV62438911; called by muse, mutect2, varscan2
- MYO7A | c.1404C>T p.H468= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs782141665; called by muse, mutect2, varscan2
- MYT1 | c.2586C>T p.H862= | Silent (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- OR5W2 | c.453G>A p.V151= | Silent (SNP) | VAF 65/235 reads (28%) | catalogued as rs746916494; called by muse, mutect2, varscan2
- RYR2 | c.4059T>C p.H1353= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as rs1209683928; called by muse, mutect2, varscan2
- THSD7A | c.2547C>T p.S849= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs572493535; called by muse, mutect2, varscan2
- ZFHX4 | c.8646C>T p.H2882= | Silent (SNP) | VAF 75/185 reads (41%) | catalogued as rs749233707, COSV99269434; called by muse, mutect2, varscan2
- ABRA | c.*1276T>C | 3'UTR (SNP) | VAF 52/125 reads (42%) | catalogued as rs1172848890; called by muse, mutect2, varscan2
- ACSS3 | c.*878C>A | 3'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- ADAM12 | c.*3986G>A | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- ATIC | c.20-80C>G | Intron (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- ATP5MC2 | chr12:53677063 A>C | 5'Flank (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- BBS7 | c.*408T>G | 3'UTR (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2
- BCL7A | chr12:122021532 G>A | 5'Flank (SNP) | VAF 30/62 reads (48%) | catalogued as rs180682804, COSV55846310; called by muse, mutect2, varscan2
- C6orf47 | c.-679C>T | 5'UTR (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2
- C6orf47 | c.-681C>A | 5'UTR (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2
- CACNG8 | c.*4098G>T | 3'UTR (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- CLMN | c.*199T>C | 3'UTR (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- DNM1 | c.1336-83G>A | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as rs545413137; called by muse, mutect2, varscan2
- EIF4E2 | c.20+98G>A | Intron (SNP) | VAF 50/94 reads (53%) | called by muse, varscan2
- FABP2 | c.*320G>A | 3'UTR (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- FAM167A | c.*1444C>T | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85529446 G>T | 5'Flank (SNP) | VAF 9/35 reads (26%) | catalogued as rs914375529; called by muse, mutect2, varscan2
- FZD6 | c.*966A>C | 3'UTR (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102180G>A | Intron (SNP) | VAF 35/273 reads (13%) | catalogued as rs528781464; called by muse, mutect2, varscan2
- IGF2 | chr11:2129484 C>T | 3'Flank (SNP) | VAF 4/94 reads (4%) | catalogued as rs1007769796; called by muse, mutect2
- IGLL5 | c.-62A>T | 5'UTR (SNP) | VAF 30/32 reads (94%) | catalogued as rs888090196, COSV104440267, COSV73250539; called by muse, mutect2, varscan2
- ITGB2 | c.1155+18C>T | Intron (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- KRT7 | chr12:52251947 C>A | 3'Flank (SNP) | VAF 62/151 reads (41%) | called by muse, mutect2, varscan2
- MOB3B | c.*167del | 3'UTR (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- MRPS18A | c.377-68T>C | Intron (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- NGEF | c.383+104del | Intron (DEL) | VAF 51/115 reads (44%) | called by mutect2, varscan2
- NUDT5 | c.-160C>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- NUDT5 | c.-161C>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- OGA | c.1985-37T>G | Intron (SNP) | VAF 79/88 reads (90%) | called by muse, mutect2, varscan2
- PCDH17 | c.*1170G>A | 3'UTR (SNP) | VAF 35/87 reads (40%) | catalogued as rs531459540, COSV100931360; called by muse, mutect2, varscan2
- PCNX1 | c.*3962A>G | 3'UTR (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- PFAS | c.*1054A>T | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- PLCB1 | c.*1757T>G | 3'UTR (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.*99G>A | 3'UTR (SNP) | VAF 51/117 reads (44%) | catalogued as rs1242593631; called by muse, mutect2, varscan2
- POU5F1B | c.*771dup | 3'UTR (INS) | VAF 8/27 reads (30%) | catalogued as rs1382868750; called by mutect2, varscan2
- PTGS2 | c.*2027A>G | 3'UTR (SNP) | VAF 47/99 reads (47%) | catalogued as rs1355198830; called by muse, mutect2, varscan2
- RAB6C | c.-341C>T | 5'UTR (SNP) | VAF 61/108 reads (56%) | catalogued as rs1220809856; called by muse, mutect2, varscan2
- RBM46 | c.*731A>G | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- SHTN1 | c.173-83C>G | Intron (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- SRD5A1 | c.*135dup | 3'UTR (INS) | VAF 48/212 reads (23%) | catalogued as rs897669034; called by mutect2, varscan2
- TAF5L | c.972+2906T>C | Intron (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- THRA | c.1110+210del | Intron (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- URGCP-MRPS24 | c.*319T>G | 3'UTR (SNP) | VAF 54/153 reads (35%) | called by muse, mutect2, varscan2
- VCAN | c.*654C>T | 3'UTR (SNP) | VAF 52/88 reads (59%) | catalogued as rs188578068; called by muse, mutect2, varscan2
- ZNF202 | c.*354C>T | 3'UTR (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- ZNF34 | chr8:144772999 C>T | 3'Flank (SNP) | VAF 21/49 reads (43%) | catalogued as rs747298644; called by muse, mutect2, varscan2
- ZNF597 | c.*153A>G | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2
- ZNF776 | c.*1974T>G | 3'UTR (SNP) | VAF 117/215 reads (54%) | called by muse, mutect2, varscan2
